Gene-level copy-number profile of tumor specimen TCGA-DD-A73D-01A from TCGA case TCGA-DD-A73D, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage II; Tumor grade: G1; Age at diagnosis: 68.3 years (24,941 days).
Specimen TCGA-DD-A73D-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.f648f4d8-248c-46bb-9390-a448b3af4405.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DD-A73D-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/47fc5a70-e131-41b6-bf3d-5a0a27653517

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 830; copy number 2: 45,199; copy number 3: 7,058; copy number 4: 2,883; copy number 5: 851; copy number 6: 2,529; copy number 7: 445; copy number 8: 22.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DD-A73D-01A-12D-A32F-01): tumor purity 0.98, ploidy 2.38, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:18,720,905–18,774,918, 2 genes: AC100800.1, RPL35P6.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3,847 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:186,375,838–198,937,471, 121 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr6:167,607–58,438,364, 1,527 genes, copy number 5–6 (broad region; genes not listed).
- chr10:8,400,860–10,462,361, 21 genes, copy number 5 (within-gene range 4–5): AC025946.1, AC025946.2, KRT8P37, CHCHD3P1, RNA5SP299, AL355333.1, LINC02676, AC044784.1, LINC00709, AL138773.1, HSP90AB7P, LINC02663, LINC02670, ELOCP3, Y_RNA, CUX2P1, AL354916.1, AL583859.1, CELF2-DT, AL583859.2, AL583859.3.
- chr10:36,089,086–38,783,108, 58 genes, copy number 5: AL355300.1, MTND5P17, MTND4P18, AL590730.1, AL590730.2, NAMPTP1, Y_RNA, AL390061.1, MKNK2P1, ARL6IP1P2, ANKRD30A, RNU6-811P, AL157387.1, LINC00993, RN7SL314P, Y_RNA, TMEM161BP1, VN1R53P, TACC1P1, MTND1P18, MTRNR2L7, AL132657.1, ZNF248, AL132657.2, ZNF33BP1, TLK2P2, AL135791.1, ZNF37CP, ZNF33CP, ZNF25, ZNF25-DT, Y_RNA, ZNF33A, RNU6-795P, AL161931.1, EIF3LP3, FXYD6P2, ZNF37A, AL117339.4, AL117339.3, AL117339.1, CCNYL4, AL133217.1, AL117339.2, HSD17B7P2, SEPTIN7P9, AL133216.2, RNU6-1118P, CICP9, AL133216.1, ABCD1P2, AL133173.2, PABPC1P12, SLC9B1P3, ACTR3BP5, CHEK2P5, AL133173.1, AL590623.1.
- chr17:26,981,694–83,095,122, 2,120 genes, copy number 6–8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 830. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
